Surgical pathology report (de-identified scan), TCGA case TCGA-FK-A4UB, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-FK-A4UB-01A (Primary Tumor).

- LAB RESULTS

SURG PATH REPORT
COLLECTION DATE/TIME:

PATH#:

FINAL DIAGNOSIS -----
Pathologist:

1. RIGHT PARATRACHEAL MASS (EXCISION): METASTATIC PAPILLARY THYROID CARCINOMA.

2. THYROID (TOTAL THYROIDECTOMY):

SPECIMEN TYPE:
Total thyroidectomy

TUMOR SITE:
Right lobe

HISTOLOGIC TYPE:
Papillary carcinoma

TUMOR SIZE:
Greatest dimension: 2 cm

FOCALITY:
Multifocal (2 major foci)

LYMPH NODES:
Metastatic carcinoma in 20 of 85 nodes (includes all parts)

EXTENT OF INVASION
PRIMARY TUMOR:
pT3: Tumor with minimal extrathyroidal extension

REGIONAL LYMPH NODES:
pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:
pMX: Cannot be assessed

MARGINS:
Involved by invasive carcinoma (superior pole). (Carcinoma extends to cauterized margin).

VENOUS/LYMPHATIC INVASION:
Present

ADDITIONAL PATHOLOGIC FINDINGS:
None identified

3. PARATRACHEAL SOFT TISSUE (NODE DISSECTION): METASTATIC PAPILLARY CARCINOMA IN ELEVEN (11) OF FIFTEEN (15) LYMPH NODES.

4. RIGHT NECK CONTENTS (NECK DISSECTION): METASTATIC PAPILLARY CARCINOMA IN EIGHT (8) OF EIGHTY THREE (83) LYMPH NODES, (LEVEL 2 (1), LEVEL 3 (5), LEVEL 4 (1) AND LEVEL 5 (1)).

ICD-O-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

hw
10/27/12

*** Unofficial lab results - do not file in patient chart. ***
*** Contact medical records for official chart copy. ***
UNLESS OTHERWISE NOTED ON THE DETAIL PAGE. ALL LAB RESULTS PERFORMED AT:

Source: NCI Genomic Data Commons file c9bfea4b-f9a4-48d9-9d4a-3e01c3d85cff (TCGA-FK-A4UB.689C08E4-6032-4933-9F13-FD89AEBD3615.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).